Somatic mutation profile of tumor specimen TCGA-21-5787-01A (aliquot TCGA-21-5787-01A-01D-1632-08) from TCGA case TCGA-21-5787, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 65.9 years (24,071 days).
Specimen TCGA-21-5787-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d8e4f83-947e-4146-b65b-7f5ffd06d869.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-21-5787-10A (Blood Derived Normal), aliquot TCGA-21-5787-10A-01D-1632-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e400c7f4-a447-4f4f-9bd7-101f4d0e972b

The open-access MAF lists 464 somatic variants for this specimen: 360 protein-altering or splice-affecting, 93 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 301, Silent 93, Nonsense Mutation 28, Frame Shift Del 13, Splice Site 8, Frame Shift Ins 7, Intron 6, RNA 2, Splice Region 2, 5'UTR 2, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1525G>A p.G509R (on ENST00000288602 / NM_001374244.1; = p.G469R on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs121913357, BM1457681, COSV56070557, COSV56082352, COSV99953015; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTN | c.131A>C p.K44T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.29); PolyPhen possibly damaging (0.61); catalogued as COSV61963901; called by muse, mutect2
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 19/40 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS18 | c.1675C>G p.P559A | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51423824; called by muse, mutect2, varscan2
- ADGRB3 | c.2204C>G p.S735* | Nonsense Mutation (SNP) | VAF 20/46 reads (43%) | catalogued as COSV65422676; called by muse, mutect2, varscan2
- ADGRF2 | c.527C>A p.T176N (on ENST00000296862 / NM_001368115.2; = p.T108N on NM_153839.7) | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV57286536; called by muse, mutect2, varscan2
- ADGRF2 | c.1007C>A p.P336H (on ENST00000296862 / NM_001368115.2; = p.P268H on NM_153839.7) | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.808); catalogued as COSV57292457; called by muse, mutect2, varscan2
- ADRA1D | c.1643A>T p.H548L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV65242142; called by muse, mutect2, varscan2
- AKT3 | c.66G>T p.W22C | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55635190; called by muse, mutect2, varscan2
- ALDH16A1 | c.360G>A p.W120* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as rs746884371, COSV53197174; called by muse, mutect2
- AMPD3 | c.2290G>T p.A764S (on ENST00000396553 / NM_001025389.2; = p.A773S on NM_000480.3) | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV101158116, COSV67332747; called by muse, mutect2, varscan2
- ANAPC4 | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | catalogued as COSV59544135, COSV59546528; called by muse, mutect2, varscan2
- ANK2 | c.1560G>A p.M520I | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.771); catalogued as COSV52191785; called by muse, mutect2, varscan2
- ANK3 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV55084834; called by muse, mutect2, varscan2
- ANO5 | c.2435C>T p.P812L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61090778; called by mutect2, varscan2
- APOB | c.9907G>T p.E3303* | Nonsense Mutation (SNP) | VAF 18/68 reads (26%) | catalogued as COSV51938884, COSV51955107; called by muse, mutect2, varscan2
- APOBEC1 | c.221G>C p.R74T | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.492); catalogued as COSV57550401; called by muse, mutect2, varscan2
- ARHGAP6 | c.1297del p.R433Efs*9 | Frame Shift Del (DEL) | VAF 35/93 reads (38%) | catalogued as COSV57293087; called by mutect2, pindel, varscan2
- ARHGEF2 | c.2859C>A p.S953R (on ENST00000361247 / NM_001162383.2; = p.S925R on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV58117813; called by muse, mutect2, varscan2
- ARNT2 | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV57591057; called by muse, mutect2
- ARSI | c.1555G>T p.A519S | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.916); catalogued as COSV60818619; called by muse, mutect2, varscan2
- ATP1A3 | c.1474C>T p.Q492* (on ENST00000545399 / NM_001256214.2; = p.Q479* on NM_152296.5) | Nonsense Mutation (SNP) | VAF 17/61 reads (28%) | catalogued as COSV100132369, COSV57491634; called by muse, mutect2, varscan2
- ATP2B1 | c.1121G>T p.G374V | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53813679; called by muse, mutect2, varscan2
- ATP6V0D1 | c.193C>G p.L65V | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); catalogued as COSV52100106; called by muse, mutect2, varscan2
- B4GALT4 | c.244C>G p.P82A | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV63296515; called by muse, mutect2
- BAZ1B | c.3547G>T p.E1183* | Nonsense Mutation (SNP) | VAF 18/97 reads (19%) | catalogued as COSV59994943; called by muse, mutect2, varscan2
- BDH1 | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs781519040, COSV64020043; called by muse, mutect2, varscan2
- BPIFB4 | c.914A>C p.K305T | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.023); catalogued as COSV64952550; called by muse, mutect2, varscan2
- BRCA2 | c.6292T>A p.S2098T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.996); catalogued as COSV66463388; called by muse, mutect2, varscan2
- BRINP1 | c.1704C>G p.S568R | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56299857, COSV56314649; called by muse, mutect2, varscan2
- BRINP3 | c.1609T>A p.L537M | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV66542847; called by muse, mutect2, varscan2
- BSN | c.472G>T p.V158F | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as COSV56528908; called by muse, mutect2, varscan2
- C10orf90 | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 39/88 reads (44%) | catalogued as COSV52965134; called by muse, mutect2, varscan2
- C14orf93 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as rs1242166141, COSV54442766; called by muse, mutect2, varscan2
- C5orf46 | c.146T>C p.L49P | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59154652; called by muse, mutect2, varscan2
- C6 | c.725A>T p.E242V | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as COSV54720012; called by muse, mutect2, varscan2
- CACNB2 | c.1300C>A p.P434T (on ENST00000324631 / NM_201596.3; = p.P379T on NM_000724.4) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV56649620; called by muse, mutect2, varscan2
- CACNG3 | c.234G>C p.K78N | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.978); catalogued as COSV50068438, COSV50085277; called by muse, mutect2, varscan2
- CALM2 | c.398G>C p.G133A | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.272); catalogued as COSV55400655; called by muse, mutect2, varscan2
- CAPN10 | c.1721C>T p.P574L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1484326383, COSV54375334; called by muse, mutect2, varscan2
- CASQ2 | c.479G>T p.R160L | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.793); catalogued as rs372283956, COSV54772010, COSV99797783; called by muse, mutect2, varscan2
- CCDC170 | c.82G>T p.V28F | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.61); catalogued as COSV53347034; called by muse, mutect2, varscan2
- CCDC181 | c.491C>A p.P164H | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63158291; called by muse, mutect2, varscan2
- CCDC7 | c.3103G>A p.D1035N | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.034); catalogued as rs763994943, COSV56552905; called by muse, mutect2, varscan2
- CCDC7 | c.3104A>T p.D1035V | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.068); catalogued as COSV56552914; called by muse, mutect2, varscan2
- CD163 | c.2303C>G p.A768G | Missense Mutation (SNP) | VAF 84/171 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV63131953, COSV63137996; called by muse, mutect2, varscan2
- CDH1 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs864622346, COSV55727767; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH10 | c.2324T>C p.L775P | Missense Mutation (SNP) | VAF 59/236 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52589257, COSV52600108; called by muse, mutect2, varscan2
- CDH12 | c.25C>A p.L9M | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV66393861; called by muse, mutect2, varscan2
- CDH8 | c.748G>T p.G250C | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54851181; called by muse, mutect2, varscan2
- CDIN1 | c.541C>A p.L181I (on ENST00000437989; = p.L83I on NM_032499.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV57714730; called by muse, mutect2, varscan2
- CDSN | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs564806482, COSV52540194; called by muse, mutect2, varscan2
- CEP192 | c.4445G>A p.S1482N | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); catalogued as rs770281767, COSV58071260; called by muse, mutect2, varscan2
- CES3 | c.689C>A p.A230D | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57595642; called by muse, mutect2, varscan2
- CFAP92 | c.137C>G p.S46C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as COSV54049145; called by muse, mutect2, varscan2
- CGNL1 | c.1223G>A p.S408N | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.099); catalogued as COSV55576198; called by muse, mutect2, varscan2
- CHAT | c.1223T>A p.L408H | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60334205; called by muse, mutect2, varscan2
- CHD3 | c.2243G>T p.R748L | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100390796, COSV57881133; called by muse, mutect2, varscan2
- CHGB | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV66761940; called by muse, mutect2, varscan2
- CHL1 | c.980T>A p.V327E (on ENST00000397491 / NM_001253387.1; = p.V343E on NM_006614.4) | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56608056; called by muse, mutect2, varscan2
- CHL1 | c.1374G>T p.Q458H (on ENST00000397491 / NM_001253387.1; = p.Q474H on NM_006614.4) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.726); catalogued as COSV56608069; called by muse, mutect2
- CHL1 | c.2735C>T p.P912L (on ENST00000397491 / NM_001253387.1; = p.P928L on NM_006614.4) | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs774246633, COSV56608078; called by muse, mutect2, varscan2
- CLYBL | c.659T>A p.L220Q | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as COSV59229832; called by muse, mutect2, varscan2
- CNNM1 | c.2663C>A p.P888H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.867); catalogued as COSV63203607; called by muse, mutect2
- CNOT2 | c.1000G>T p.G334W | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57507506; called by muse, mutect2, varscan2
- CNR1 | c.559A>T p.N187Y | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV62991054; called by muse, mutect2, varscan2
- COL12A1 | c.8257G>T p.G2753C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59399853; called by muse, mutect2, varscan2
- COL22A1 | c.4249G>T p.G1417* | Nonsense Mutation (SNP) | VAF 18/65 reads (28%) | catalogued as COSV100280611, COSV57363213; called by muse, mutect2, varscan2
- COL24A1 | c.3610G>T p.G1204W | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100994105; called by muse, mutect2, varscan2
- CRACD | c.2761G>T p.A921S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.02); catalogued as COSV51732791; called by muse, mutect2, varscan2
- CRISP3 | c.716A>G p.K239R (on ENST00000371159 / NM_001368123.1; = p.K221R on NM_006061.4) | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs755162365, COSV53823616; called by muse, mutect2, varscan2
- CSGALNACT2 | c.1401A>T p.L467F | Missense Mutation (SNP) | VAF 73/159 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV65678478; called by muse, mutect2, varscan2
- CSMD3 | c.2162G>A p.C721Y (on ENST00000297405 / NM_001363185.1; = p.C617Y on NM_052900.3) | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52334742, COSV99836666; called by muse, mutect2, varscan2
- CTNNA2 | c.1366G>T p.D456Y | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV58184640; called by muse, mutect2, varscan2
- CTNND2 | c.1271A>G p.Y424C | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1220418471, COSV58932006; called by muse, mutect2, varscan2
- CYP11B1 | c.302A>C p.Q101P | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.876); catalogued as rs1180336478, COSV52830718; called by muse, mutect2, varscan2
- CYP24A1 | c.665A>G p.K222R | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.139); catalogued as COSV53777013; called by muse, mutect2, varscan2
- CYP2C9 | c.1210C>A p.P404T | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1364340491, COSV53253404, COSV99583126; called by muse, mutect2, varscan2
- CYP2W1 | c.405C>A p.S135R | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs747421506, COSV58271709; called by muse, mutect2, varscan2
- DCC | c.3310G>C p.V1104L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.829); catalogued as COSV71441562; called by muse, mutect2, varscan2
- DCDC1 | c.2356A>G p.T786A | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV60860571; called by muse, mutect2
- DGKZ | c.2923G>T p.A975S (on ENST00000454345 / NM_001105540.2; = p.A787S on NM_003646.4) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV58995978; called by muse, mutect2
- DHX15 | c.944G>T p.R315L | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV61025483, COSV61029506; called by muse, mutect2, varscan2
- DIP2B | c.1720-2A>C p.X574_splice | Splice Site (SNP) | VAF 61/96 reads (64%) | catalogued as COSV56593051; called by muse, mutect2, varscan2
- DLG4 | c.997G>C p.G333R (on ENST00000399506 / NM_001321075.3; = p.G376R on NM_001365.4) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57242493; called by muse, mutect2, varscan2
- DMRTA1 | c.1022G>T p.R341M | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV57925539; called by muse, mutect2, varscan2
- DNAH7 | c.7906G>T p.E2636* | Nonsense Mutation (SNP) | VAF 36/69 reads (52%) | catalogued as COSV56789273; called by muse, mutect2, varscan2
- DOCK10 | c.5771A>T p.D1924V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV51429436; called by muse, mutect2, varscan2
- DOCK2 | c.2527G>T p.V843F | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV56991359; called by muse, mutect2, varscan2
- DOCK4 | c.3289C>A p.Q1097K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); catalogued as COSV69855754; called by muse, mutect2, varscan2
- DST | c.20207G>T p.G6736V (on ENST00000361203 / NM_001374722.1; = p.G4433V on NM_015548.5) | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55043166; called by muse, mutect2, varscan2
- DYRK1A | c.1591C>T p.P531S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.194); catalogued as rs757603372, COSV58297404; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYSF | c.3474G>T p.M1158I | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV50629178, COSV99251169; called by muse, mutect2, varscan2
- EDARADD | c.388del p.D130Ifs*7 (on ENST00000334232 / NM_145861.4; = p.D120Ifs*7 on NM_080738.4) | Frame Shift Del (DEL) | VAF 25/62 reads (40%) | catalogued as COSV62061055; called by mutect2, pindel, varscan2
- ELAVL2 | c.817G>A p.G273R | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.187); catalogued as COSV56372001; called by muse, mutect2, varscan2
- ERC2 | c.2331G>C p.K777N | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV55668024; called by muse, mutect2
- ERICH3 | c.3356C>T p.P1119L | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV100444288, COSV58620064; called by muse, mutect2, varscan2
- ESYT2 | c.618G>T p.W206C (on ENST00000613624; = p.W130C on NM_020728.3) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51757175; called by muse, mutect2, varscan2
- EXOSC4 | c.674A>T p.H225L | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV60156648; called by muse, mutect2, varscan2
- FABP12 | c.196A>T p.K66* | Nonsense Mutation (SNP) | VAF 25/173 reads (14%) | catalogued as COSV64617880; called by muse, mutect2, varscan2
- FAM160A2 | c.185G>C p.G62A | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs1391514164, COSV56415201; called by muse, mutect2, varscan2
- FAM217A | c.334T>A p.F112I | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.173); catalogued as COSV51162893; called by muse, mutect2, varscan2
- FAM50B | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as COSV66654570, COSV66655272; called by muse, mutect2, varscan2
- FAM83B | c.1273G>T p.V425L | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.123); catalogued as COSV60927459; called by muse, mutect2, varscan2
- FAM83B | c.1926G>C p.L642F | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as rs1042396093, COSV60927466; called by muse, mutect2
- FBXO15 | c.1519G>T p.G507W | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54049132; called by muse, mutect2, varscan2
- FBXO4 | c.418A>C p.M140L | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.924); catalogued as COSV55854438; called by muse, mutect2, varscan2
- FIGN | c.889G>T p.G297C | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV60772170; called by muse, mutect2, varscan2
- FIP1L1 | c.675G>C p.E225D | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.931); catalogued as COSV61000096; called by muse, mutect2, varscan2
- FMO4 | c.319A>T p.K107* | Nonsense Mutation (SNP) | VAF 21/42 reads (50%) | catalogued as COSV63002007; called by muse, mutect2, varscan2
- FOXH1 | c.980T>C p.L327P | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1237185569, COSV56763197; called by muse, mutect2, varscan2
- FRS3 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs142682061; called by muse, mutect2, varscan2
- FXYD1 | c.111G>T p.Q37H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV54344246; called by muse, mutect2, varscan2
- GABRA4 | c.761G>T p.R254L | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51935956, COSV99973869; called by muse, mutect2, varscan2
- GABRG1 | c.1297C>G p.H433D | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.811); catalogued as COSV54954851, COSV54962609; called by muse, mutect2, varscan2
- GALNT13 | c.413T>A p.V138E | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1406272616, COSV67241051; called by muse, varscan2
- GASK1B | c.1125+1G>T p.X375_splice | Splice Site (SNP) | VAF 11/36 reads (31%) | catalogued as COSV56712224; called by muse, varscan2
- GDF5 | c.632A>T p.D211V | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV65503799; called by muse, mutect2, varscan2
- GFRAL | c.289C>A p.L97I | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as COSV61236001; called by muse, mutect2, varscan2
- GJA10 | c.223A>T p.I75F | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65356466; called by muse, mutect2, varscan2
- GNAI3 | c.932A>G p.N311S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as rs746144403, COSV63984605; called by muse, mutect2, varscan2
- GRIN3A | c.1613C>A p.P538H | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100701900; called by muse, mutect2, varscan2
- GRIN3B | c.2488C>A p.H830N | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52263879; called by muse, mutect2, varscan2
- GRIP1 | c.1990C>A p.Q664K (on ENST00000359742 / NM_001379345.1; = p.Q612K on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as COSV54045299; called by muse, mutect2, varscan2
- GRM5 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59617004, COSV59632416; called by muse, mutect2, varscan2
- GRM7 | c.1254G>T p.M418I | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as COSV63174208; called by mutect2, varscan2
- GUCY1A2 | c.2095G>T p.V699L | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV56480549, COSV56503884; called by muse, mutect2, varscan2
- GYS2 | c.1474G>C p.D492H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs753854327, COSV53927222, COSV53929650; called by muse, mutect2, varscan2
- H2AC15 | c.89G>C p.R30P | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV57585632, COSV57586672; called by muse, mutect2, varscan2
- HAUS6 | c.572A>G p.Q191R | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV63253123; called by muse, mutect2
- HCN1 | c.1939C>A p.L647M | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100302643; called by muse, mutect2
- HCN1 | c.431A>C p.Y144S | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV57539678; called by muse, mutect2, varscan2
- HEATR5A | c.1066T>C p.C356R | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.242); catalogued as COSV66346195; called by muse, mutect2, varscan2
- HEY2 | c.340G>C p.A114P | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV64240338, COSV64240832; called by muse, varscan2
- HOXB13 | c.435C>A p.D145E | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV51707436; called by muse, mutect2, varscan2
- HOXB3 | c.59C>A p.S20* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV61143165, COSV61145571; called by muse, mutect2, varscan2
- HSP90AB1 | c.853A>T p.T285S | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV62336480; called by muse, mutect2, varscan2
- HSP90B1 | c.550G>C p.D184H | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.764); catalogued as COSV55358248; called by muse, mutect2
- HTR3A | c.1341del p.V448Cfs*12 | Frame Shift Del (DEL) | VAF 20/48 reads (42%) | catalogued as COSV55470950; called by mutect2, pindel, varscan2
- HTR4 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs200526857, COSV58803728; called by muse, mutect2, varscan2
- HUNK | c.451A>G p.K151E | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.747); catalogued as COSV54235021; called by muse, mutect2, varscan2
- IFI16 | c.268A>C p.K90Q | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.171); catalogued as COSV55540778; called by muse, mutect2, varscan2
- IFTAP | c.490A>T p.T164S | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV57560072; called by muse, mutect2, varscan2
- IL27RA | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54603469; called by muse, mutect2, varscan2
- IL7 | c.242T>A p.L81* | Nonsense Mutation (SNP) | VAF 12/74 reads (16%) | catalogued as COSV55678462; called by muse, mutect2, varscan2
- IRS4 | c.2517G>T p.R839S | Missense Mutation (SNP) | VAF 76/151 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV64536204; called by muse, mutect2, varscan2
- ISX | c.19C>A p.P7T | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.591); catalogued as rs138420595; called by muse, mutect2, varscan2
- ITGA10 | c.2689G>C p.E897Q | Missense Mutation (SNP) | VAF 41/327 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65198552; called by muse, mutect2, varscan2
- ITGA11 | c.172G>T p.V58L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777781459, COSV59882429; called by muse, mutect2, varscan2
- ITGAX | c.2789G>T p.S930I | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51652222; called by muse, mutect2, varscan2
- KALRN | c.8537T>A p.F2846Y (on ENST00000360013 / NM_001024660.4; = p.F1149Y on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV52265565; called by muse, mutect2, varscan2
- KARS1 | c.959G>C p.R320P | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56694090, COSV56694677; called by muse, mutect2, varscan2
- KCNA5 | c.1237C>A p.L413I | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764965372, COSV52909033; called by muse, mutect2
- KCNJ5 | c.500T>C p.L167P | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV57971661; called by muse, mutect2, varscan2
- KCNN2 | c.932G>T p.G311V (on ENST00000264773; = p.G523V on NM_021614.4) | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV53300206; called by muse, mutect2, varscan2
- KCNT1 | c.2356G>A p.V786I (on ENST00000488444; = p.V805I on NM_020822.3) | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.478); catalogued as rs376955682; called by muse, mutect2, varscan2
- KDM3B | c.1449G>C p.L483F | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.991); catalogued as COSV58695960; called by muse, mutect2, varscan2
- KIAA1549 | c.5128G>A p.V1710I | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.84); PolyPhen benign (0.024); catalogued as COSV54330633; called by muse, mutect2, varscan2
- KIAA2026 | c.1370G>T p.R457M | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV67358050; called by muse, mutect2, varscan2
- KIF2B | c.1849A>G p.S617G | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV52136034; called by muse, varscan2
- KLF11 | c.1126A>T p.I376F | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs769368043, COSV59941769; called by muse, mutect2, varscan2
- KLHDC10 | c.200G>T p.R67M | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV59054273; called by muse, mutect2, varscan2
- KY | c.1776C>A p.N592K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs753076111, COSV71018790; called by muse, mutect2, varscan2
- LAMA1 | c.6074C>T p.T2025M | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs369357135, CM156866, COSV67545084; called by muse, mutect2, varscan2
- LCP2 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50448097, COSV50469854; called by muse, mutect2, varscan2
- LILRB1 | c.943C>A p.Q315K (on ENST00000427581; = p.Q279K on NM_006669.6) | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV61122120; called by muse, mutect2, varscan2
- LIMA1 | c.83A>G p.K28R | Missense Mutation (SNP) | VAF 47/80 reads (59%) | SIFT tolerated (0.37); PolyPhen benign (0.32); catalogued as COSV57968956; called by muse, mutect2, varscan2
- LRBA | c.4000A>T p.R1334* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as COSV63966221; called by muse, mutect2, varscan2
- LRP1 | c.3073G>T p.G1025W | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54501461; called by muse, mutect2, varscan2
- LRP1 | c.5173A>T p.S1725C | Missense Mutation (SNP) | VAF 89/154 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV54527944; called by muse, mutect2, varscan2
- LRRIQ3 | c.338A>T p.K113M | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63050680; called by muse, mutect2, varscan2
- LRRN3 | c.505C>G p.L169V | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57824335; called by muse, mutect2, varscan2
- LRRTM4 | c.660C>G p.I220M | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.101); catalogued as COSV101297659, COSV69142924; called by muse, mutect2, varscan2
- LSM8 | c.139A>T p.S47C | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50800742; called by muse, mutect2, varscan2
- LTBP2 | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs370158492; called by muse, mutect2, varscan2
- MAP2K3 | c.381C>G p.Y127* (on ENST00000342679 / NM_145109.3; = p.Y98* on NM_002756.4) | Nonsense Mutation (SNP) | VAF 37/120 reads (31%) | catalogued as COSV57564464, COSV57578769; called by muse, mutect2, varscan2
- MAPK8 | c.445C>T p.H149Y | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64411272; called by muse, mutect2
- MAST2 | c.1237G>A p.V413M | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.854); catalogued as COSV63621644; called by muse, mutect2, varscan2
- MCOLN2 | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV52300026; called by muse, mutect2, varscan2
- MCOLN3 | c.1292G>T p.W431L | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62016494; called by muse, mutect2, varscan2
- MDH1 | c.363G>T p.K121N | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.972); catalogued as COSV51865351; called by muse, mutect2, varscan2
- MDN1 | c.1194C>G p.I398M | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65531373; called by muse, mutect2, varscan2
- MED25 | c.306G>C p.K102N | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV57207360, COSV57207728; called by muse, mutect2, varscan2
- MMP17 | c.1640G>T p.G547V | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as rs1029804898, COSV62181592; called by muse, mutect2, varscan2
- MPP6 | c.917dup p.K307Efs*14 | Frame Shift Ins (INS) | VAF 20/94 reads (21%) | catalogued as rs757450051; ClinVar: not provided; called by mutect2, varscan2
- MTARC1 | c.659C>G p.S220W | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65055695, COSV65056392; called by muse, mutect2, varscan2
- MTSS1 | c.1906G>A p.G636R | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV52676462; called by muse, mutect2, varscan2
- MUC16 | c.39607C>T p.L13203F | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); catalogued as rs1429476884, COSV66697162; called by muse, mutect2, varscan2
- MUC16 | c.22382C>A p.T7461N | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.147); catalogued as rs1401912017, COSV67497765; called by muse, mutect2, varscan2
- MUC2 | c.1210G>T p.V404F | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.02); catalogued as COSV61250296; called by muse, mutect2, varscan2
- MUC5B | c.7859C>A p.P2620H | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.354); catalogued as rs1452632200, COSV71595975; called by muse, mutect2, varscan2
- MYH8 | c.124G>T p.V42L | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV67973509; called by muse, mutect2
- NCKAP5 | c.4070G>T p.S1357I | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV58466893, COSV58478251; called by muse, mutect2, varscan2
- NDUFA12 | c.84C>T p.F28= | Splice Region (SNP) | VAF 15/114 reads (13%) | catalogued as COSV59846403, COSV59846552; called by muse, mutect2, varscan2
- NEB | c.5603C>T p.S1868F | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.266); catalogued as COSV51444687; called by muse, mutect2, varscan2
- NEURL2 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV51945534; called by muse, mutect2, varscan2
- NFATC1 | c.1852G>T p.G618C | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53710389; called by muse, mutect2, varscan2
- NHS | c.3796G>T p.G1266C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.416); catalogued as COSV66283619; called by muse, mutect2, varscan2
- NIN | c.5301G>T p.K1767N (on ENST00000382041 / NM_182946.1; = p.K1054N on NM_016350.4) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55408407; called by muse, mutect2, varscan2
- NLRP10 | c.1525G>T p.E509* | Nonsense Mutation (SNP) | VAF 24/59 reads (41%) | catalogued as COSV60783015; called by muse, mutect2, varscan2
- NOS2 | c.415C>A p.L139I | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.422); catalogued as COSV58227874; called by muse, mutect2, varscan2
- NOX5 | c.262C>A p.L88M | Missense Mutation (SNP) | VAF 67/139 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV52996869; called by muse, mutect2, varscan2
- NTRK3 | c.11C>G p.S4C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.271); catalogued as COSV58146450; called by muse, mutect2, varscan2
- NTS | c.327A>C p.K109N | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT tolerated (0.22); PolyPhen benign (0.046); catalogued as COSV55457237; called by muse, mutect2, varscan2
- NUBPL | c.283A>T p.N95Y | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); catalogued as COSV55276594; called by muse, mutect2, varscan2
- NUCB1 | c.964C>T p.Q322* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV54388478; called by muse, mutect2, varscan2
- NUP133 | c.1699G>C p.D567H | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs767139944, COSV54575762; called by muse, mutect2, varscan2
- NUP188 | c.689G>C p.S230T | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV65365212; called by muse, mutect2, varscan2
- OPCML | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148167692, COSV59410223, COSV59453522; called by muse, mutect2, varscan2
- OPTC | c.881A>C p.H294P | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV65868785; called by muse, mutect2, varscan2
- OR10A4 | c.706C>T p.H236Y | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.384); catalogued as COSV65842659; called by muse, mutect2, varscan2
- OR10G3 | c.227C>A p.S76Y | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV57811290; called by muse, mutect2, varscan2
- OR10H5 | c.236C>G p.P79R | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV58279357; called by muse, mutect2, varscan2
- OR10J5 | c.575C>A p.T192N | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated (0.32); PolyPhen benign (0.208); catalogued as COSV58387911; called by muse, mutect2, varscan2
- OR10Q1 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as COSV57472135; called by muse, mutect2, varscan2
- OR10Q1 | c.595G>T p.V199L | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.103); catalogued as COSV57472141; called by muse, mutect2, varscan2
- OR1G1 | c.629G>C p.C210S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV61030709; called by muse, mutect2, varscan2
- OR2B11 | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV59509512; called by muse, mutect2
- OR2T1 | c.851T>C p.L284P | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63543013; called by muse, mutect2, varscan2
- OR4C16 | c.415T>C p.C139R | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58941903; called by muse, mutect2, varscan2
- OR5B3 | c.137T>G p.L46W | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV58676191, COSV58678840; called by muse, mutect2, varscan2
- OR5H15 | c.722G>A p.C241Y | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62947587; called by muse, mutect2, varscan2
- OR6B2 | c.374C>A p.A125D | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1422978647; called by muse, mutect2, varscan2
- OR6C6 | c.152C>A p.P51H | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.013); catalogued as COSV64456357; called by muse, mutect2, varscan2
- OR7D4 | c.196C>A p.L66M | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58071411; called by muse, mutect2, varscan2
- OR8H2 | c.448G>T p.V150L | Missense Mutation (SNP) | VAF 86/182 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as COSV57947716; called by muse, mutect2, varscan2
- OSR2 | c.691C>A p.Q231K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.18); catalogued as COSV52559300; called by muse, varscan2
- PADI3 | c.549G>T p.M183I | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV64935522; called by muse, mutect2, varscan2
- PARD3B | c.2338A>T p.S780C (on ENST00000406610 / NM_001302769.2; = p.S718C on NM_152526.6) | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62532818; called by muse, mutect2, varscan2
- PARPBP | c.1420G>T p.G474* | Nonsense Mutation (SNP) | VAF 17/36 reads (47%) | catalogued as COSV59677003; called by muse, mutect2, varscan2
- PCDHB14 | c.1534C>A p.H512N | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.082); catalogued as COSV53391642; called by muse, mutect2, varscan2
- PDE11A | c.1206C>A p.D402E | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.497); catalogued as COSV53698291, COSV53710570; called by muse, mutect2, varscan2
- PDIK1L | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.792); catalogued as COSV65323033; called by muse, mutect2, varscan2
- PDYN | c.490G>C p.A164P | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV54103632; called by muse, mutect2, varscan2
- PGM2 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as rs757988566, COSV67939654; called by muse, mutect2, varscan2
- PIGG | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.941); catalogued as COSV56321880; called by muse, mutect2, varscan2
- PIGG | c.460G>C p.A154P | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56321890; called by muse, mutect2, varscan2
- PIP4K2A | c.440T>C p.I147T | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as rs1377111633, COSV60542854; called by muse, mutect2
- PKD1 | c.10373C>A p.P3458H (on ENST00000262304 / NM_001009944.3; = p.P3457H on NM_000296.4) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.025); catalogued as COSV99239219; called by muse, mutect2, varscan2
- PNLIPRP3 | c.91G>C p.G31R | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as COSV65049867; called by muse, mutect2, varscan2
- POT1 | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62931672; called by muse, mutect2, varscan2
- POU4F2 | c.824C>A p.T275N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55587046; called by muse, varscan2
- PPIG | c.828G>T p.E276D | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV53641754, COSV53646562; called by muse, mutect2, varscan2
- PRDM9 | c.194-1G>C p.X65_splice | Splice Site (SNP) | VAF 8/53 reads (15%) | catalogued as rs1448957025, COSV57014072, COSV99689521; called by muse, mutect2, varscan2
- PRKAA2 | c.523G>C p.G175R | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64803185, COSV64806965; called by muse, mutect2, varscan2
- PRKN | c.633A>C p.K211N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as CM003860, COSV58283832; called by muse, mutect2, varscan2
- PRSS23 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV54707788; called by muse, mutect2, varscan2
- PSMC6 | c.383A>G p.E128G (on ENST00000612399; = p.E114G on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as rs11545962, COSV71629426; called by muse, mutect2, varscan2
- PTPRT | c.2982G>A p.R994= | Splice Region (SNP) | VAF 22/90 reads (24%) | catalogued as COSV62026507; called by muse, mutect2, varscan2
- PXDNL | c.2120C>A p.S707Y | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1394704139, COSV62499665; called by muse, mutect2, varscan2
- PYGB | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV53823358; called by muse, mutect2, varscan2
- RARB | c.616G>T p.G206C (on ENST00000383772 / NM_001290216.2; = p.G199C on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV58071349; called by muse, mutect2, varscan2
- RPL14 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.117); catalogued as COSV59084065; called by muse, mutect2, varscan2
- RTL9 | c.772C>A p.L258M | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71826512; called by muse, mutect2, varscan2
- RYR3 | c.1145A>C p.K382T | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV66810018; called by muse, mutect2, varscan2
- RYR3 | c.3827T>A p.F1276Y | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as COSV66810021; called by muse, mutect2, varscan2
- SAMD15 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as COSV53628170; called by muse, mutect2, varscan2
- SAMHD1 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs1277922979, COSV99484369; called by muse, mutect2, varscan2
- SCG3 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.794); catalogued as COSV55023519; called by muse, mutect2, varscan2
- SCN2A | c.801G>T p.L267F | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51857026; called by muse, mutect2, varscan2
- SCN3A | c.5405C>A p.P1802H | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51826071; called by muse, mutect2, varscan2
- SCN7A | c.4339A>C p.K1447Q | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV69274999; called by muse, mutect2, varscan2
- SDK2 | c.3853G>T p.G1285C | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101168857; called by muse, mutect2, varscan2
- SEC23IP | c.2839C>T p.R947* | Nonsense Mutation (SNP) | VAF 36/72 reads (50%) | catalogued as rs1444349785, COSV64833303; called by muse, mutect2, varscan2
- SEC61A2 | c.409T>A p.Y137N | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53655604; called by muse, mutect2, varscan2
- SEMA3C | c.1567G>A p.D523N | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54843436, COSV54851083; called by muse, mutect2, varscan2
- SGCB | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV67341606; called by muse, mutect2, varscan2
- SI | c.1515C>A p.D505E | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.147); catalogued as COSV52303463; called by muse, mutect2, varscan2
- SI | c.22G>T p.G8* | Nonsense Mutation (SNP) | VAF 15/56 reads (27%) | catalogued as rs750431387, COSV52303486; called by muse, mutect2, varscan2
- SLC12A1 | c.1265C>A p.T422N | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV57712310; called by muse, mutect2, varscan2
- SLC12A3 | c.2386C>G p.P796A | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV52639631; called by muse, mutect2, varscan2
- SLC22A9 | c.173C>G p.T58S | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV54170744; called by muse, mutect2, varscan2
- SLC24A3 | c.1606+1G>T p.X536_splice | Splice Site (SNP) | VAF 6/34 reads (18%) | catalogued as COSV60134580; called by muse, varscan2
- SLC24A4 | c.638C>A p.S213Y | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54122383; called by muse, mutect2, varscan2
- SLC45A4 | c.382G>T p.V128F (on ENST00000517878 / NM_001286646.2; = p.V77F on NM_001080431.2) | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV50196467; called by muse, mutect2, varscan2
- SMPD1 | c.514A>G p.I172V | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV54971087; called by muse, mutect2, varscan2
- SNAI2 | c.292G>T p.D98Y | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.174); catalogued as COSV50080495, COSV50080861; called by muse, mutect2, varscan2
- SNTG2 | c.905G>T p.W302L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58008761; called by muse, varscan2
- SPATA18 | c.242G>T p.W81L | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV54650970; called by muse, mutect2, varscan2
- SPTBN5 | c.4057A>G p.K1353E | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV58028796; called by muse, mutect2, varscan2
- SPTLC3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 12/55 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV65469033; called by muse, mutect2, varscan2
- SRARP | c.83-2A>T p.X28_splice | Splice Site (SNP) | VAF 73/305 reads (24%) | catalogued as COSV61498117; called by muse, mutect2, varscan2
- STMN2 | c.530T>A p.L177Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV55222980; called by muse, mutect2
- SYT3 | c.38C>A p.A13E | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as COSV58899416; called by muse, mutect2, varscan2
- TDRD5 | c.190G>T p.V64F | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54251324; called by muse, mutect2, varscan2
- TENM3 | c.6593G>T p.R2198L | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.972); catalogued as COSV69308961, COSV69312882; called by muse, mutect2, varscan2
- TGFBR3 | c.1946G>T p.R649M | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.079); catalogued as COSV53031768; called by muse, mutect2, varscan2
- TGM5 | c.1557G>T p.M519I (on ENST00000220420 / NM_201631.4; = p.M437I on NM_004245.4) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.029); catalogued as COSV99589382; called by muse, mutect2, varscan2
- THBS2 | c.1340C>A p.S447Y | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64682500; called by muse, mutect2, varscan2
- THSD7B | c.217G>T p.G73W | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55648336, COSV55742726; called by muse, mutect2, varscan2
- TIAM1 | c.3943G>T p.V1315L | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV54577194; called by muse, mutect2, varscan2
- TIMM44 | c.862+1G>C p.X288_splice | Splice Site (SNP) | VAF 13/61 reads (21%) | catalogued as COSV54494974; called by muse, mutect2, varscan2
- TMEM63C | c.1056G>T p.M352I | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as COSV53609525; called by muse, mutect2, varscan2
- TMTC2 | c.979G>T p.G327C | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV58285376; called by muse, mutect2, varscan2
- TRIM11 | c.1052G>T p.R351L | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as rs752779667, COSV52860487; called by muse, mutect2, varscan2
- TRIM9 | c.2041C>A p.P681T | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53625639; called by muse, mutect2, varscan2
- TRMU | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.216); catalogued as rs754687615, COSV51991698; called by muse, mutect2, varscan2
- TWNK | c.1484G>T p.R495M | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV52972510; called by muse, mutect2, varscan2
- TXNDC16 | c.1961A>C p.K654T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as COSV55987921; called by muse, mutect2, varscan2
- UBE2V2 | c.41G>T p.R14L | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.42); catalogued as rs780298410, COSV72879295; called by muse, mutect2, varscan2
- UGT3A1 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57099180, COSV57104049; called by muse, mutect2, varscan2
- UHRF1BP1 | c.4180G>C p.E1394Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV51961058; called by muse, mutect2, varscan2
- UIMC1 | c.1871G>T p.R624L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101022163, COSV65893656; called by muse, mutect2, varscan2
- UNC5A | c.568G>T p.V190L | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs1390007618, COSV56173043; called by muse, mutect2, varscan2
- UNC5C | c.1768C>A p.P590T | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV71662581; called by muse, mutect2
- UNC79 | c.3002C>A p.A1001D (on ENST00000393151 / NM_001346218.2; = p.A824D on NM_020818.5) | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV56414164; called by muse, mutect2, varscan2
- URI1 | c.925G>T p.D309Y | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV56353496; called by muse, mutect2, varscan2
- USP30 | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV57451813; called by muse, mutect2, varscan2
- VAT1L | c.275T>C p.I92T | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.966); catalogued as rs777907129, COSV56829676; called by muse, mutect2, varscan2
- VCAM1 | c.1972G>T p.A658S | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.849); catalogued as rs146573744; called by muse, mutect2, varscan2
- VCAN | c.9162G>T p.E3054D | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV54117772; called by muse, mutect2, varscan2
- VPS13D | c.12692G>T p.R4231L | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50670974, COSV50694804; called by muse, mutect2, varscan2
- VPS4B | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV53069270, COSV53071036; called by muse, mutect2, varscan2
- VPS8 | c.3364G>T p.E1122* (on ENST00000625842 / NM_001349294.1; = p.E1120* on NM_015303.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as COSV54997631; called by muse, mutect2
- VRK2 | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60881000; called by muse, mutect2, varscan2
- VSNL1 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 29/82 reads (35%) | catalogued as COSV54604058; called by muse, mutect2, varscan2
- WDPCP | c.1463T>C p.L488P | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV55425136; called by muse, mutect2
- WNT2B | c.531T>A p.H177Q (on ENST00000369684 / NM_024494.3; = p.H158Q on NM_004185.4) | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV56677481; called by muse, mutect2, varscan2
- XPO6 | c.2315C>T p.P772L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1054512749, COSV58972176; called by muse, mutect2, varscan2
- ZFPM2 | c.937C>A p.L313I | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV65876336; called by muse, mutect2, varscan2
- ZFPM2 | c.2353C>A p.H785N | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV65876342; called by muse, mutect2, varscan2
- ZMYM1 | c.3121G>C p.D1041H | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV63254018; called by muse, mutect2
- ZNF233 | c.1068T>A p.C356* | Nonsense Mutation (SNP) | VAF 8/58 reads (14%) | catalogued as COSV61935082; called by muse, mutect2
- ZNF256 | c.881C>A p.P294H | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.975); catalogued as COSV56600001; called by muse, mutect2, varscan2
- ZNF267 | c.227-1G>T p.X76_splice | Splice Site (SNP) | VAF 10/46 reads (22%) | catalogued as COSV56251993; called by muse, mutect2, varscan2
- ZNF462 | c.7466G>T p.C2489F | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.205); catalogued as COSV52951944; called by muse, mutect2, varscan2
- ZNF536 | c.1237G>T p.V413L | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as COSV62835444; called by muse, mutect2, varscan2
- ZNF540 | c.1300A>T p.T434S | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.309); catalogued as COSV57111738; called by muse, mutect2, varscan2
- ZNF595 | c.969G>C p.Q323H | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV59554266; called by muse, mutect2, varscan2
- ZNF607 | c.1885G>T p.A629S | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62206550; called by muse, mutect2, varscan2
- ZNF773 | c.392G>A p.R131K | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.053); catalogued as COSV56590683; called by muse, mutect2, varscan2
- ZNF780A | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.916); catalogued as rs143775764; called by muse, mutect2, varscan2
- ZNF804B | c.2884C>T p.P962S | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV60858356; called by muse, mutect2, varscan2
- ZSWIM8 | c.839C>G p.S280* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as COSV67135102; called by muse, mutect2, varscan2
- ZSWIM8 | c.1687C>G p.P563A | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.017); catalogued as COSV67135112; called by muse, mutect2, varscan2
- ACACA | c.5790C>A p.F1930L | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, varscan2
- DAGLA | c.111dup p.V38Rfs*9 | Frame Shift Ins (INS) | VAF 11/31 reads (35%) | called by mutect2, pindel, varscan2
- FCGR1A | c.722C>A p.T241K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.669); called by mutect2, varscan2
- FNDC11 | c.344del p.G115Afs*60 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- FRG2 | c.337T>C p.C113R | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- FUBP1 | c.1638_1654del p.Q546Hfs*15 | Frame Shift Del (DEL) | VAF 47/109 reads (43%) | called by mutect2, pindel, varscan2
- HAVCR1 | c.16dup p.V6Gfs*44 | Frame Shift Ins (INS) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- HYDIN | c.12039G>C p.W4013C | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGKV1D-43 | c.97C>A p.L33M | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.574); called by muse, mutect2
- LPAR2 | c.227_228del p.A76Gfs*2 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | called by pindel, varscan2
- NBAS | c.7056del p.T2353Lfs*? | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | called by mutect2, pindel, varscan2
- OR4A16 | c.51dup p.D18Rfs*3 | Frame Shift Ins (INS) | VAF 21/46 reads (46%) | called by mutect2, pindel, varscan2
- OTOP1 | c.1576del p.S526Afs*18 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | called by mutect2, pindel, varscan2
- PICK1 | c.916_917del p.A306Pfs*108 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | called by pindel, varscan2
- PPP4R4 | c.245dup p.M82Ifs*7 | Frame Shift Ins (INS) | VAF 4/15 reads (27%) | called by mutect2, pindel, varscan2
- PRAMEF8 | c.997C>A p.H333N | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RNF181 | c.118_119del p.L40Gfs*20 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel
- SEPHS1 | c.298-2del p.X100_splice | Splice Site (DEL) | VAF 8/26 reads (31%) | called by mutect2, varscan2
- SLC39A12 | c.1169del p.F390Sfs*59 | Frame Shift Del (DEL) | VAF 18/89 reads (20%) | called by pindel, varscan2*
- SMOC1 | c.1015del p.I339Lfs*25 | Frame Shift Del (DEL) | VAF 12/67 reads (18%) | called by mutect2, pindel, varscan2
- STK11 | c.152_153insC p.M51Ifs*112 | Frame Shift Ins (INS) | VAF 11/28 reads (39%) | called by mutect2, pindel, varscan2
- SYNRG | c.2503C>T p.Q835* | Nonsense Mutation (SNP) | VAF 17/100 reads (17%) | called by muse, mutect2, varscan2
- TAF1D | c.123_144del p.K42Ffs*27 | Frame Shift Del (DEL) | VAF 17/73 reads (23%) | called by mutect2, pindel
- TXNRD1 | c.638dup p.C214Lfs*4 (on ENST00000525566 / NM_001093771.3; = p.C116Lfs*4 on NM_003330.4) | Frame Shift Ins (INS) | VAF 13/25 reads (52%) | called by mutect2, pindel, varscan2
- ZNF488 | c.219G>T p.E73D | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ABCA12 | c.5178G>A p.L1726= (on ENST00000272895 / NM_173076.3; = p.L1408= on NM_015657.3) | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV55977712; called by muse, mutect2, varscan2
- ALPP | c.1278C>A p.G426= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV67397178, COSV67398338; called by muse, mutect2, varscan2
- ANKRD30A | c.2478A>G p.Q826= (on ENST00000611781; = p.Q770= on NM_052997.2) | Silent (SNP) | VAF 4/31 reads (13%) | called by mutect2, varscan2
- APOA4 | c.801G>C p.L267= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV63361227; called by muse, mutect2, varscan2
- APOC1 | c.207A>T p.S69= | Silent (SNP) | VAF 80/216 reads (37%) | catalogued as COSV52992429; called by muse, mutect2, varscan2
- ASB10 | c.1236C>T p.Y412= (on ENST00000420175 / NM_001142459.2; = p.Y397= on NM_080871.4) | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV52001060; called by muse, mutect2, varscan2
- ATP13A2 | c.387G>T p.R129= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV58704275; called by muse, mutect2, varscan2
- BMP7 | c.483C>A p.S161= | Silent (SNP) | VAF 75/205 reads (37%) | catalogued as COSV67782849; called by muse, mutect2, varscan2
- BUB1B | c.858G>A p.E286= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV55017230; called by muse, mutect2, varscan2
- CADPS | c.3690C>A p.A1230= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs982168584, COSV51905961; called by muse, mutect2, varscan2
- CALR | c.9A>G p.L3= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV57138089; called by muse, mutect2, varscan2
- CBX2 | c.453G>T p.V151= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV53970361; called by muse, mutect2, varscan2
- CCDC89 | c.1122A>T p.P374= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV57035009; called by muse, mutect2, varscan2
- CHRNA6 | c.36G>T p.G12= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV52380189, COSV52381235; called by muse, mutect2, varscan2
- CLASRP | c.1026C>T p.A342= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs766206717, COSV55519757; called by muse, mutect2
- CORIN | c.1803C>T p.G601= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV56700494; called by muse, mutect2, varscan2
- DDX54 | c.882G>T p.T294= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV58376381; called by muse, mutect2, varscan2
- DNTTIP2 | c.1461A>T p.A487= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as COSV63284705; called by muse, mutect2, varscan2
- ELK3 | c.54G>A p.Q18= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as COSV57388497; called by muse, mutect2, varscan2
- FAM83B | c.240T>C p.D80= | Silent (SNP) | VAF 60/198 reads (30%) | catalogued as COSV60927449; called by muse, mutect2, varscan2
- FILIP1L | c.3393T>A p.L1131= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV63387798; called by muse, mutect2, varscan2
- FOXD4L3 | c.624A>G p.Q208= | Silent (SNP) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- GABRA4 | c.1053C>A p.A351= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV51935948, COSV99973798; called by muse, mutect2, varscan2
- GALNT1 | c.1059G>A p.T353= | Silent (SNP) | VAF 50/109 reads (46%) | catalogued as rs1444044240, COSV52453080; called by muse, mutect2, varscan2
- GTF3C3 | c.2412C>T p.L804= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as rs1252215807, COSV55834851; called by muse, mutect2, varscan2
- GYS2 | c.1674T>A p.R558= | Silent (SNP) | VAF 58/101 reads (57%) | catalogued as COSV53929641; called by muse, mutect2, varscan2
- HK3 | c.1398G>T p.V466= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV52845239; called by muse, mutect2, varscan2
- HYDIN | c.7401C>A p.V2467= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs769836197; called by mutect2, varscan2
- IL27 | c.655C>A p.R219= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs373848919, COSV60494496; called by muse, mutect2, varscan2
- IQGAP3 | c.4314G>T p.R1438= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV63255002; called by muse, mutect2, varscan2
- IRAK3 | c.708G>A p.K236= | Silent (SNP) | VAF 31/57 reads (54%) | catalogued as rs772462205, COSV54166408; called by muse, mutect2, varscan2
- ITPRIP | c.738C>T p.V246= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV53393353; called by muse, mutect2, varscan2
- KCNK13 | c.462C>A p.A154= | Silent (SNP) | VAF 41/103 reads (40%) | catalogued as COSV56418282; called by muse, mutect2, varscan2
- KCNQ2 | c.1104C>G p.T368= | Silent (SNP) | VAF 40/101 reads (40%) | catalogued as COSV60435653, COSV60439835; called by muse, mutect2, varscan2
- KIF2B | c.1827C>A p.T609= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as rs915182598, COSV52136019; called by muse, varscan2
- KLF17 | c.297C>T p.S99= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV64857143; called by muse, mutect2, varscan2
- KRTAP19-6 | c.69T>C p.Y23= | Silent (SNP) | VAF 64/114 reads (56%) | catalogued as COSV61844421; called by muse, mutect2, varscan2
- MAGEB18 | c.147C>A p.P49= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100305656; called by muse, mutect2
- MBL2 | c.216C>A p.P72= | Silent (SNP) | VAF 19/142 reads (13%) | catalogued as COSV100906428; called by muse, mutect2, varscan2
- MGAM | c.3204G>C p.L1068= | Silent (SNP) | VAF 29/146 reads (20%) | catalogued as COSV72075997; called by muse, mutect2, varscan2
- MMP2 | c.1134A>T p.T378= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV54605769; called by muse, mutect2, varscan2
- MMP26 | c.687T>A p.T229= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV56174247; called by muse, mutect2, varscan2
- MUC16 | c.40530C>A p.V13510= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV66691162; called by muse, mutect2, varscan2
- NKX6-2 | c.510C>A p.T170= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV63974129; called by muse, mutect2, varscan2
- NLRP14 | c.2709G>T p.T903= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as COSV55065882, COSV55072804; called by muse, mutect2, varscan2
- NOS1AP | c.1044C>T p.H348= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as COSV62640655; called by muse, mutect2, varscan2
- NOTCH1 | c.2631G>T p.P877= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV53063349, COSV53099240; called by muse, mutect2, varscan2
- NRG1 | c.1851C>A p.R617= (on ENST00000405005 / NM_013964.5; = p.R622= on NM_013956.5) | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV55177627; called by muse, mutect2, varscan2
- NTSR2 | c.648G>T p.V216= | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as COSV60992949; called by muse, mutect2, varscan2
- OPN1SW | c.183C>A p.R61= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV50823663; called by muse, mutect2, varscan2
- OR4K14 | c.330G>T p.G110= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV59294440; called by muse, mutect2, varscan2
- OR4X1 | c.147C>A p.A49= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV60722736; called by muse, mutect2, varscan2
- OR51A2 | c.471G>A p.L157= | Silent (SNP) | VAF 36/205 reads (18%) | catalogued as COSV66748857; called by muse, mutect2, varscan2
- OR51A4 | c.471G>A p.L157= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as COSV66749503, COSV66750147; called by muse, mutect2, varscan2
- OR9Q1 | c.147C>A p.I49= | Silent (SNP) | VAF 35/151 reads (23%) | catalogued as COSV59048107; called by muse, mutect2, varscan2
- OR9Q2 | c.330C>A p.I110= | Silent (SNP) | VAF 43/102 reads (42%) | catalogued as COSV61112761, COSV61112858; called by muse, mutect2, varscan2
- OSR2 | c.900G>C p.R300= (on ENST00000297565 / NM_001142462.3; = p.G273A on NM_053001.3) | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV52559310; called by muse, mutect2
- PARP3 | c.1137G>T p.R379= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV51753773; called by muse, mutect2, varscan2
- PCDHA4 | c.1461C>T p.N487= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs139246893; called by muse, mutect2, varscan2
- PCSK2 | c.735C>T p.F245= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV52744450; called by muse, mutect2, varscan2
- PCSK4 | c.1539C>T p.P513= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs1472511871, COSV56301645; called by muse, mutect2
- PDPR | c.1002T>A p.P334= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV55357389; called by muse, mutect2, varscan2
- PDZD8 | c.1650C>T p.H550= | Silent (SNP) | VAF 81/174 reads (47%) | catalogued as COSV57828869; called by mutect2, varscan2
- PDZRN3 | c.2394G>A p.T798= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs373980614; called by muse, mutect2, varscan2
- PHKB | c.876A>T p.T292= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV54535719; called by muse, mutect2, varscan2
- PLCH1 | c.3822T>C p.V1274= (on ENST00000340059 / NM_001130960.2; = p.V1266= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/134 reads (17%) | catalogued as COSV58211099; called by muse, mutect2, varscan2
- POMT1 | c.1515C>T p.S505= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV61227972; called by muse, mutect2, varscan2
- RAB10 | c.483G>A p.K161= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV53093095; called by muse, mutect2, varscan2
- RBP3 | c.762G>A p.V254= | Silent (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- RIMS2 | c.3075A>T p.A1025= (on ENST00000666250 / NM_001348490.2; = p.A833= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV99166063, COSV99202564; called by muse, mutect2, varscan2
- RTL9 | c.672C>G p.P224= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as COSV71826510; called by muse, mutect2, varscan2
- RTTN | c.2319G>A p.S773= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as rs758513533, COSV55345481; called by muse, mutect2, varscan2
- SBK2 | c.357C>T p.I119= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs1188504890, COSV60016260; called by muse, mutect2
- SETD3 | c.777C>T p.P259= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV59287534; called by muse, mutect2, varscan2
- SFT2D2 | c.420C>T p.S140= | Silent (SNP) | VAF 42/95 reads (44%) | catalogued as COSV54801076; called by muse, mutect2, varscan2
- SIM1 | c.663C>A p.A221= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV53495966, COSV53497316; called by mutect2, varscan2
- SLC25A31 | c.129G>C p.R43= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV55422210; called by muse, mutect2, varscan2
- SLC9A9 | c.573T>C p.A191= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV57247215; called by muse, mutect2, varscan2
- SNTG2 | c.132G>T p.R44= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV58008750; called by muse, mutect2, varscan2
- SPTB | c.4125C>T p.L1375= | Silent (SNP) | VAF 22/92 reads (24%) | catalogued as COSV67635449; called by muse, mutect2, varscan2
- SVIL | c.2508G>T p.R836= (on ENST00000355867 / NM_021738.3; = p.R410= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV63442351, COSV63448800; called by muse, mutect2, varscan2
- TDRD6 | c.5658C>T p.G1886= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as rs373939719; called by muse, mutect2, varscan2
- TIMD4 | c.1056A>G p.L352= | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as rs1183107515, COSV50861003; called by muse, mutect2, varscan2
- TLCD3A | c.384C>G p.L128= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs1189978656, COSV100021054, COSV56747728; called by muse, mutect2
- TRIM43 | c.285C>A p.T95= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV99720177; called by muse, mutect2, varscan2
- VN1R4 | c.840C>A p.L280= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV60805791; called by muse, mutect2, varscan2
- VPS8 | c.3363G>T p.V1121= (on ENST00000625842 / NM_001349294.1; = p.V1119= on NM_015303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV54997622; called by muse, mutect2
- VWF | c.693C>T p.T231= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as COSV54629901, COSV54636183; called by muse, mutect2, varscan2
- ZMAT3 | c.54G>T p.S18= | Silent (SNP) | VAF 18/133 reads (14%) | catalogued as COSV60995638; called by muse, mutect2, varscan2
- ZNF202 | c.1518A>G p.E506= | Silent (SNP) | VAF 22/92 reads (24%) | catalogued as COSV60248782; called by muse, mutect2, varscan2
- ZNF554 | c.1146C>T p.C382= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs202167387, COSV57887173; called by muse, mutect2, varscan2
- ZNF676 | c.459C>A p.V153= (on ENST00000650058; = p.V121= on NM_001001411.3) | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as COSV68095177; called by muse, mutect2, varscan2
- ZNF711 | c.36G>T p.T12= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV52159555; called by muse, mutect2, varscan2
- AL359922.1 | c.348-35294C>A | Intron (SNP) | VAF 7/20 reads (35%) | catalogued as CM112061, CM112062, CS021185, COSV64265217, COSV64265629, COSV64269377; called by muse, mutect2, varscan2
- AMDHD2 | c.970+38C>T | Intron (SNP) | VAF 11/49 reads (22%) | catalogued as rs377376699; called by muse, mutect2, varscan2
- C16orf82 | c.-146G>T | 5'UTR (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- DLG2 | c.205-65661G>T | Intron (SNP) | VAF 31/90 reads (34%) | catalogued as COSV99720404; called by muse, mutect2, varscan2
- MACF1 | c.15832-11001G>T | Intron (SNP) | VAF 30/100 reads (30%) | catalogued as COSV57147086; called by muse, mutect2, varscan2
- PARVB | c.712+396G>T | Intron (SNP) | VAF 15/45 reads (33%) | called by muse, mutect2, varscan2
- RPS26P15 | n.186T>C | RNA (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2, varscan2
- SH2D6 | n.644C>T | RNA (SNP) | VAF 10/45 reads (22%) | catalogued as rs751255189, COSV61064356; called by muse, mutect2, varscan2
- SLC3A2 | chr11:62854650 T>A | 5'Flank (SNP) | VAF 30/60 reads (50%) | called by muse, mutect2, varscan2
- TTN | c.10360+4791G>A | Intron (SNP) | VAF 42/84 reads (50%) | catalogued as COSV60382820; called by muse, mutect2, varscan2
- ZNF207 | c.-91G>T | 5'UTR (SNP) | VAF 60/143 reads (42%) | catalogued as rs780529544, COSV58302321; called by muse, mutect2, varscan2
